CCDI case PBBVHR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ab9ba1fe-31b5-4336-9d30-8ab42f540e06

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.9 years (3,598 days).

Biospecimens (4 samples)
- Sample 0DI6KL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DI6KT, 0DI6L1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIAC1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
